Somatic mutation profile of tumor specimen MP2PRT-PARLDF-TMP1-A (aliquot MP2PRT-PARLDF-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARLDF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,512 days).
Specimen MP2PRT-PARLDF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75dc2ec6-9a17-405f-ab9d-ffa3c88d1b3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLDF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLDF-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f25eaf6e-6efe-41d1-a6eb-0491dc4c7d5c

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 20, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXO1 | c.65C>G p.S22W | Missense Mutation (SNP) | VAF 235/1146 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65426970; called by muse, mutect2, varscan2
- ANKRD30A | c.728A>T p.H243L (on ENST00000611781; = p.H187L on NM_052997.2) | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV64618228; called by muse, mutect2, varscan2
- C14orf93 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1197592731; called by muse, mutect2, varscan2
- CACNG4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 39/492 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1466892036, COSV50924354, COSV50925321; called by muse, mutect2
- KCNT1 | c.686C>T p.A229V (on ENST00000488444; = p.A248V on NM_020822.3) | Missense Mutation (SNP) | VAF 230/565 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs575954363; called by muse, mutect2, varscan2
- LAMC3 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 153/422 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750461310, COSV100736144; called by muse, varscan2
- OGDHL | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 156/293 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs760518509, COSV65102202; called by muse, mutect2, varscan2
- PCDHGB1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 59/555 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs747653356; called by muse, mutect2, varscan2
- PPARGC1B | c.2536C>T p.R846W | Missense Mutation (SNP) | VAF 91/701 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs751402065; called by muse, varscan2
- SEC24A | c.1363T>C p.C455R | Missense Mutation (SNP) | VAF 113/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555566478; called by muse, mutect2, varscan2
- TSPAN13 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as rs892001134; called by muse, mutect2
- ZNF765 | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as COSV67182982; called by muse, mutect2, varscan2
- ALPK2 | c.4700T>C p.V1567A | Missense Mutation (SNP) | VAF 181/478 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DHRS13 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 247/557 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506994 del TGTAT | Missense Mutation (DEL) | VAF 49/65 reads (75%) | called by pindel*, varscan2
- LACTB2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LTK | c.2353G>C p.D785H | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- RALBP1 | c.1153_1154insGCCCCGG p.M385Sfs*43 | Frame Shift Ins (INS) | VAF 118/379 reads (31%) | called by mutect2, pindel*, varscan2
- SYNPO2 | c.3594G>T p.E1198D | Missense Mutation (SNP) | VAF 179/412 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TTN | c.66037G>C p.E22013Q (on ENST00000591111; = p.E14589Q on NM_003319.4) | Missense Mutation (SNP) | VAF 17/523 reads (3%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF99 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CNR2 | c.165C>G p.L55= | Silent (SNP) | VAF 147/639 reads (23%) | catalogued as rs192526527; called by muse, mutect2
- ENKUR | c.459C>T p.V153= | Silent (SNP) | VAF 56/292 reads (19%) | called by muse, mutect2, varscan2
- LRFN2 | c.390C>T p.I130= | Silent (SNP) | VAF 293/661 reads (44%) | catalogued as COSV57827700, COSV57829989; called by muse, mutect2, varscan2
- MANSC4 | c.180T>C p.S60= | Silent (SNP) | VAF 194/458 reads (42%) | called by muse, mutect2, varscan2
- TMEM44 | c.90C>T p.F30= | Silent (SNP) | VAF 75/812 reads (9%) | catalogued as rs762372222; called by muse, mutect2
- TRIM22 | c.303A>G p.G101= | Silent (SNP) | VAF 275/603 reads (46%) | called by muse, mutect2, varscan2
